Somatic mutation profile of tumor specimen TARGET-15-SJMPAL016342-09A.2 (aliquot TARGET-15-SJMPAL016342-09A.2-01D) from TARGET case TARGET-15-SJMPAL016342, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.9 years (335 days).
Specimen TARGET-15-SJMPAL016342-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89720c54-feb0-456f-8590-ad413f00852d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL016342-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL016342-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abc34487-124f-405b-98c7-567bb18afb53

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 33/162 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CAMSAP2 | c.1709C>A p.P570H (on ENST00000236925 / NM_001297707.2; = p.P559H on NM_203459.3) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.149); called by muse, mutect2
- ILF2 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.074); called by muse, mutect2, varscan2
